Somatic mutation profile of tumor specimen TCGA-BS-A0U5-01A (aliquot TCGA-BS-A0U5-01A-11D-A10G-09) from TCGA case TCGA-BS-A0U5, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 76.5 years (27,945 days).
Specimen TCGA-BS-A0U5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 615eefd6-fbb3-43ba-a51d-1c5613fcb27a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BS-A0U5-10A (Blood Derived Normal), aliquot TCGA-BS-A0U5-10A-01D-A10G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cb36690-65e2-4608-a26d-fa78d77a3fbf

The open-access MAF lists 57 somatic variants for this specimen: 46 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 39, Silent 11, Frame Shift Ins 2, Frame Shift Del 2, In Frame Del 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1730_1744del p.R577_L581del (on ENST00000521381 / NM_181523.3; = p.R307_L311del on NM_181504.4) | In Frame Del (DEL) | VAF 75/253 reads (30%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PTEN | c.491del p.K164Rfs*3 | Frame Shift Del (DEL) | VAF 32/63 reads (51%) | catalogued as rs786204900, COSV64297274; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ANXA7 | c.1165C>T p.R389* (on ENST00000372919 / NM_001320880.2; = p.R367* on NM_001156.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 42/149 reads (28%) | catalogued as rs772606696, COSV65824647; called by muse, mutect2, varscan2
- ASCC3 | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 192/501 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.05); catalogued as COSV61235031; called by muse, mutect2, varscan2
- ATP10A | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.069); catalogued as rs1220387658, COSV63526299; called by muse, mutect2, varscan2
- BUB1 | c.2769C>G p.F923L | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV57067794; called by muse, mutect2, varscan2
- C12orf60 | c.643G>T p.V215F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs767214530, COSV57453542; called by muse, mutect2, varscan2
- C14orf39 | c.1762dup p.*588Lfs*3 | Frame Shift Ins (INS) | VAF 42/93 reads (45%) | catalogued as rs780875081; called by mutect2, varscan2
- CD5L | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.343); catalogued as rs1172805927, COSV63823397; called by muse, mutect2, varscan2
- CILP | c.2602C>T p.R868W | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as rs1041653391, COSV56027395; called by muse, mutect2, varscan2
- CMKLR1 | c.919G>T p.A307S (on ENST00000312143 / NM_001142344.2; = p.A305S on NM_004072.3) | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as COSV56442546; called by muse, mutect2, varscan2
- COASY | c.1690G>A p.D564N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs757786032, COSV55900230; called by muse, mutect2, varscan2
- CTCF | c.1027T>C p.Y343H | Missense Mutation (SNP) | VAF 67/195 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV50534779; called by muse, mutect2, varscan2
- DAPK3 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs991187490, COSV56665454; called by muse, mutect2, varscan2
- DGKK | c.2663G>A p.R888H | Missense Mutation (SNP) | VAF 106/247 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1170156492, COSV65709672; called by muse, mutect2, varscan2
- DNAH3 | c.7815C>A p.N2605K | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.765); catalogued as COSV54557899; called by muse, mutect2, varscan2
- GCLM | c.770G>A p.R257K | Missense Mutation (SNP) | VAF 90/242 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64687644; called by muse, mutect2, varscan2
- IRX3 | c.665G>A p.G222D | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs151141618; called by muse, mutect2, varscan2
- ITGAL | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs202150477; called by muse, mutect2, varscan2
- LARGE2 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs1222346567, COSV57651352; called by muse, mutect2, varscan2
- LRIG2 | c.2695C>T p.R899W | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.586); catalogued as rs375681331; called by muse, mutect2, varscan2
- LYST | c.3941G>T p.G1314V | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV67715481; called by muse, mutect2, varscan2
- MAGEA11 | c.35G>T p.C12F | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.308); catalogued as COSV60755532; called by muse, mutect2, varscan2
- MGAM | c.2501G>A p.R834Q | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778528944, COSV72073567; called by muse, mutect2, varscan2
- MINDY3 | c.1069G>C p.G357R | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53221118, COSV53225091; called by muse, mutect2, varscan2
- NADK | c.893A>T p.N298I | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58277697; called by muse, mutect2, varscan2
- NALCN | c.4820G>A p.R1607Q | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs370886839, COSV99218045; called by muse, mutect2, varscan2
- NRAP | c.2356T>C p.Y786H (on ENST00000359988 / NM_001322945.2; = p.Y751H on NM_006175.4) | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63494663; called by muse, mutect2, varscan2
- NSDHL | c.302T>C p.V101A | Missense Mutation (SNP) | VAF 81/227 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.366); catalogued as COSV64745522; called by muse, mutect2, varscan2
- PCDHA2 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as COSV65370933; called by muse, mutect2, varscan2
- PITPNM1 | c.2266G>T p.V756L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV62710267; called by muse, mutect2
- POLR3GL | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs370170498; called by muse, mutect2, varscan2
- PRRC2B | c.1715A>G p.H572R | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61944193; called by muse, mutect2, varscan2
- SARNP | c.304-2A>T p.X102_splice | Splice Site (SNP) | VAF 36/88 reads (41%) | catalogued as COSV60244795; called by muse, mutect2, varscan2
- SEPTIN4 | c.859A>G p.I287V | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs371918956; called by muse, mutect2, varscan2
- SLC24A3 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs376513919; called by muse, mutect2, varscan2
- SNTB1 | c.890T>G p.V297G | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV67330065; called by muse, mutect2, varscan2
- SPIRE2 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.187); catalogued as rs769855187, COSV65558034; called by muse, mutect2, varscan2
- SRRM2 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as rs577375094, COSV57081628; called by muse, mutect2, varscan2
- TECTA | c.3757G>C p.E1253Q | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as COSV50832510; called by muse, mutect2, varscan2
- TTK | c.1241G>A p.R414Q | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs778540061, COSV57884319; called by muse, mutect2, varscan2
- ZFP91 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs765360071, COSV60162635; called by muse, mutect2, varscan2
- ZNF367 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs1564141248, COSV64547879; called by muse, mutect2, varscan2
- ZNRF3 | c.919C>T p.R307W (on ENST00000544604 / NM_001206998.2; = p.R207W on NM_032173.3) | Missense Mutation (SNP) | VAF 69/88 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60431866; called by muse, mutect2, varscan2
- ARID1A | c.1451_1452dup p.Y485Pfs*135 | Frame Shift Ins (INS) | VAF 143/474 reads (30%) | called by mutect2, pindel, varscan2
- SCN9A | c.2779_2785del p.E927* (on ENST00000303354; = p.E916* on NM_002977.3) | Frame Shift Del (DEL) | VAF 57/203 reads (28%) | called by mutect2, pindel, varscan2
- ABO | c.903C>T p.D301= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as rs1218633829, COSV71743715; called by muse, mutect2, varscan2
- ANKS1A | c.3159G>A p.T1053= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs144689346; called by muse, mutect2, varscan2
- GUCY2F | c.1479T>C p.R493= | Silent (SNP) | VAF 101/268 reads (38%) | catalogued as COSV54309634; called by muse, mutect2, varscan2
- LRRIQ4 | c.588C>T p.D196= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs1167416990, COSV61619016; called by muse, mutect2, varscan2
- LYAR | c.801C>T p.G267= | Silent (SNP) | VAF 104/254 reads (41%) | catalogued as rs776356297, COSV58644469; called by muse, mutect2, varscan2
- MFGE8 | c.213C>G p.V71= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs750819532; called by muse, mutect2, varscan2
- OR13H1 | c.861G>C p.L287= | Silent (SNP) | VAF 29/116 reads (25%) | catalogued as COSV58548799; called by muse, mutect2, varscan2
- PCM1 | c.4044C>T p.S1348= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV59589314; called by muse, mutect2, varscan2
- RHOBTB3 | c.1287G>A p.T429= | Silent (SNP) | VAF 45/104 reads (43%) | catalogued as COSV66103176; called by muse, mutect2, varscan2
- SLC7A11 | c.699G>T p.T233= | Silent (SNP) | VAF 19/255 reads (7%) | catalogued as COSV54928267, COSV54934324; called by muse, mutect2
- TOP3B | c.2415C>T p.P805= | Silent (SNP) | VAF 14/21 reads (67%) | catalogued as rs765129084, COSV54286972; called by muse, mutect2, varscan2
